Surgical pathology report (de-identified scan), TCGA case TCGA-24-1418, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1418-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL

Service:

Accession #:

OTHER Taken:

MRN :

Received:

Hospital #:

Accessioned:

Patient Type:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- SURFACE AND PARENCHYMAL DEPOSITS OF PRIMARY PERITONEAL SEROUS CARCINOMA, LARGEST PARENCHYMAL DEPOSIT MEASURING 0.45 CM (SEE DESCRIPTION)
- MULLERIAN INCLUSION CYST

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- PARATUBAL SOFT TISSUE SURFACE DEPOSITS OF SEROUS CARCINOMA
- NO EVIDENCE OF INTRALUMINAL OR MUCOSAL TUMOR

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- SURFACE DEPOSITS OF PRIMARY PERITONEAL SEROUS CARCINOMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- PARATUBAL SOFT TISSUE SURFACE DEPOSITS OF SEROUS CARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM WITH MILD FOCAL ADENOMYOSIS

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- SURFACE IMPLANTS OF PRIMARY PERITONEAL SEROUS CARCINOMA

OMENTUM, EXCISION

- EXTENSIVE INVOLVEMENT BY SEROUS CARCINOMA (LARGEST FOCUS > 2 CM)

[page 2 of 3]
Microscopic Description and Comment:

Bilateral ovaries and fallopian tubes were submitted in their entirety and show no evidence of salpingeal in situ, intraluminal, or ovarian parenchymal deposits of serous carcinoma measuring > 0.5 cm.

History:

Total abdominal hysterectomy, bilateral salpingo-oophorectomy, and omentectomy.

Specimen(s) Received:

A: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
B: OMENTUM

Gross Description:

The specimens are received in two containers of formalin, each labeled [REDACTED]. The first container is labeled [REDACTED]. It contains a uterus with bilateral adnexa. The uterus has a tan-brown nodular, serosal surface consistent with implants and measures 8.0 x 4.5 x 3.5 cm. The tan 3.2 x 3.2 cm ectocervix is unremarkable with a 0.7 cm slit-like os. The uterus has been previously opened to show a 2.5 x 0.5 cm canal and a 3.5 x 1.5 tan-brown unremarkable endometrium. The right ovary measures 2.2 x 1.8 x 1.3 cm and is sectioned to show a tan-yellow parenchyma. The right fallopian tube measures 6.5 cm 1.5 x 1.0 cm with numerous firm yellow-tan nodules on the paratubal soft tissue surface. The fallopian tube is sectioned to show a lumen ranging from 0.1 cm to 0.5 cm. The left ovary measures 3.0 x 1.5 x 1.5 cm and is sectioned to show a tan-yellow, vaguely nodular cut surface. The left fallopian tube 3.5 x 1.0 x 0.8 cm and has numerous, vaguely nodular tan-white firm areas adhered to paratubal soft tissue. Labeled A1 and A2 - right ovary; A3 - right fallopian tube; A4 and A5 - left ovary; A6 and A7 - left fallopian tube; A8 - posterior cervix; A9 - anterior cervix; A10 - posterior uterus; A11 - anterior uterus; A12-14 - right ovary and fallopian tube, entirely submitted; A15-17 Left ovary and fallopian tube entirely submitted. Jar 2.

The second container is labeled "omentum." It contains ~ 20 pieces of previously sectioned omentum, measuring 18 x 18 x 1.5 cm in aggregate. The omentum is further sectioned to show firm white-tan tissue intermixed with fibrofatty tissue, grossly consistent with metastatic omental caking, largest focus measuring > 2 cm.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location(s) of the tumor(s) is/are peritoneal primary

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)
Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Metastatic involvement of the omentum is present

[page 3 of 3]
TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file d8a33d39-4721-4420-8d56-2c65d35bc806 (TCGA-24-1418.14FDB291-BA79-4852-9242-02DC191CA8C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).